Surgical pathology report (de-identified scan), TCGA case TCGA-24-2281, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2281-01A (Primary Tumor).

[page 1 of 4]
TCGA-24-2281

SURGICAL PATHOLOGY REPORT
FINAL

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN:

Hospital:

Patient Type:

Accession

Taken:

Received:

Accessioned:

Reported:

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

OVARY, RIGHT, OOPHORECTOMY

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

- SEE SYNOPSIS

FALLOPIAN TUBE, RIGHT, SALPINGECTOMY

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA BY DIRECT EXTENSION

OVARY, LEFT, OOPHORECTOMY

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

- FOCAL LYMPHOVASCULAR SPACE INVASION BY ADENOCARCINOMA IS IDENTIFIED

FALLOPIAN TUBE, LEFT, SALPINGECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

SOFT TISSUE, ANTERIOR CUL-DE-SAC, BIOPSY

- UNREMARKABLE FIBROADIPOSE TISSUE

SOFT TISSUE, POSTERIOR CUL-DE-SAC, BIOPSY

- UNREMARKABLE FIBROADIPOSE TISSUE

SOFT TISSUE, LEFT PELVIC SIDEWALL, BIOPSY

- UNREMARKABLE FIBROADIPOSE TISSUE

SOFT TISSUE, RIGHT PELVIC SIDEWALL, BIOPSY

- UNREMARKABLE FIBROADIPOSE TISSUE

SOFT TISSUE, RIGHT GUTTER, BIOPSY

- UNREMARKABLE FIBROADIPOSE TISSUE

SOFT TISSUE, LEFT GUTTER, BIOPSY

- UNREMARKABLE FIBROADIPOSE TISSUE

LYMPH NODES, LEFT PELVIC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN EIGHT LYMPH NODES

LYMPH NODES, RIGHT PELVIC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN SIX LYMPH NODES

LYMPH NODES, RIGHT COMMON PERIAORTIC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES

LYMPH NODES, LEFT COMMON PERIAORTIC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES

[page 2 of 4]
[REDACTED]

OMENTUM, OMENTECTOMY

- FOCAL ENDOSALPINGIOSIS

- NO EVIDENCE OF MALIGNANCY IN ONE INCIDENTAL LYMPH NODE

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By [REDACTED]

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'right tube and ovary,' consisting of a 3.5 x 2.7 x 2.5 cm ovary with smooth serosal surface, and solid cystic areas. Solid component measures 2.5 x 1.5 x 1.4 cm, and 2 x 1.5 x 1.4 cm (two nodules) with papillary cut surface. Unremarkable fallopian tube measures 6 x 0.8 cm. A section is cut for frozen section (FS1). Rest for permanents," by [REDACTED]. A second intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up 'left tube and ovary,' consisting of a 3 x 2 cm pink-white ovary with pink smooth surface and portion of unremarkable fallopian tube. Ovarian cut surface is tan-white. Tumor and fallopian tube for tumor bank. No frozen. All for permanents," by [REDACTED].

FS1: Right ovary

- "Serous papillary carcinoma [REDACTED]"

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis [REDACTED]

History:

The patient is a [REDACTED] with bilateral adnexal masses; her CA125 is greater than 100. Operative procedure: EUA, exploratory laparotomy, bilateral salpingo-oophorectomy.

Specimen(s) Received:

- A: OVARY AND TUBE, RIGHT
- B: OVARY AND TUBE, LEFT
- C: ANTERIOR CUL-DE-SAC
- D: POSTERIOR CUL-DE-SAC
- E: LEFT PELVIC SIDEWALL
- F: RIGHT PELVIC SIDEWALL
- G: RIGHT GUTTER
- H: LEFT GUTTER
- I: LYMPH NODE, LEFT PELVIC
- J: LYMPH NODE, RIGHT PELVIC
- K: LYMPH NODE, RIGHT COMMON PERIAORTIC
- L: LYMPH NODE, LEFT COMMON PERIAORTIC
- M: OMENTUM

Gross Description

The specimens are received in thirteen formalin-filled containers, each labeled [REDACTED]. The first container is labeled "right tube and ovary." It contains a previously-opened ovary that weighs 19.17 grams, along with the attached fallopian tube. The measurements are consistent with those in the intraoperative consultation. Also in the container is a frozen section cassette

[page 3 of 4]
labeled "FS1," with tan-white tissue measuring 2.1 x 2 x 0.2 cm. Submitted as A1. Additional sections submitted in A2 to A4. A5 - fallopian tube. [REDACTED]
The second container is labeled "left tube and ovary." It contains a 15.07 gram tubo-ovarian complex. The ovary measures 2.5 x 2 x 1.6 cm. The fallopian tube is adhered to the ovary, and measures 2.2 x 0.6 cm. The surface of the ovary is irregular. Labeled B1 to B4 - ovary; B5 - ovary and fallopian tube. [REDACTED]
The third container is labeled "anterior cul-de-sac." It contains a white-tan fragment of fatty tissue measuring 1.2 x 1.2 x 1 cm. [REDACTED]
The fourth container is labeled "posterior cul-de-sac." It contains a soft tissue fragment measuring 1.1 x 0.2 x 0.2 cm. [REDACTED]
The fifth container is labeled "left pelvic sidewall." It contains a 1 x 0.3 x 0.3 cm tan tissue. [REDACTED]
The sixth container is labeled "right pelvic sidewall." It contains a 1 x 0.5 x 0.3 cm yellow-tan fatty tissue. [REDACTED]
The seventh container is labeled "right gutter." It contains a 1 x 0.4 x 0.4 cm fatty tissue. [REDACTED]
The eighth container is labeled "left gutter." It contains two yellow-tan fragments of tissue measuring 0.4 x 0.3 x 0.2 cm each. [REDACTED]
The ninth container is labeled "left pelvic lymph nodes." It contains fatty tissue measuring, in aggregate, 6 x 5 x 2 cm. Labeled I1 to I5 - one putative lymph node bisected each; I6 - multiple single lymph nodes. [REDACTED]
The tenth container is labeled "right pelvic lymph nodes." It contains fibrofatty tissue measuring ~7 x 5 x 1 cm. Labeled J1 to J5 - single putative lymph node bisected; J6 - individual single lymph node. [REDACTED]
The eleventh container is labeled "right common peri-aortic lymph node." It contains a single 3 x 2 x 1 cm yellow fatty tissue. Entire tissue appears to be a putative single lymph node. Serially sectioned. [REDACTED]

The twelfth container is labeled "left common peri-aortic lymph node." It contains two fatty fragments of tissue measuring 1.5 x 1.5 x 0.6 and 1.5 x 1 x 0.3 cm. Labeled L1 - smaller fragment bisected; L2 - larger fragment in multiple sections. [REDACTED]
The thirteenth container is labeled "omentum." It contains a 100-gram omentum measuring 15 x 5 x 1 cm. There are no papillary projections, or tumor nodules noted on the omental surface. Labeled M1 to M5. Jar 2. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is absent

PRIMARY TUMOR (T)

[page 4 of 4]
[REDACTED]

Based on the above information, the primary tumor is classified as extension and/or implants on uterus and/or tubes (T2a/IIA)

REGIONAL LYMPH NODES (N)

The regional lymph nodes are classified as no regional lymph node metastasis (N0)

The total number of regional lymph nodes examined is 19

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage has insufficient data to assign stage (Stage X)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

The performance characteristics of some immunohistochemical stains, fluorescence in-situ hybridization tests and immunophenotyping by flow cytometry cited in this report (if any) were determined by the [REDACTED] as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the [REDACTED]

[REDACTED]. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the US Food and Drug Administration. [REDACTED]

[REDACTED] determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to the report:

This test was developed and its performance characteristics determined by the [REDACTED]

Source: NCI Genomic Data Commons file f1cc47c4-d981-4e4a-a37b-8cb65c643971 (TCGA-24-2281.363DC00F-480D-4A3F-8950-80A6BC0B7DD8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).